Somatic mutation profile of cancer-model specimen HCM-WCMC-0949-C67-85A (3D Organoid; aliquot HCM-WCMC-0949-C67-85A-01D-A88H-36), derived from the primary tumor of HCMI case HCM-WCMC-0949-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma, non-invasive; Tissue or organ of origin: Bladder, NOS; Age at diagnosis: 82.5 years (30,133 days).
Specimen HCM-WCMC-0949-C67-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fd0d519-8b42-4ba9-b4f7-8634788e9e13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0949-C67-12A (Saliva), aliquot HCM-WCMC-0949-C67-12A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28d43968-00ea-4636-8282-28db17b46775

The open-access MAF lists 440 somatic variants for this specimen: 338 protein-altering or splice-affecting, 84 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 282, Silent 84, Frame Shift Ins 37, Nonsense Mutation 12, Intron 7, Frame Shift Del 3, 5'Flank 3, 3'UTR 3, Splice Site 2, 5'UTR 2, 3'Flank 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 192/507 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.15088C>T p.R5030C | Missense Mutation (SNP) | VAF 92/454 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1555185875, CM138453, COSV56417619; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 35/162 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.2995G>A p.E999K | Missense Mutation (SNP) | VAF 91/299 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs796053126, CM139611, COSV51835030; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 70/332 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as rs1415738240, COSV65313177; called by muse, mutect2, varscan2
- AC006059.2 | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 122/412 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as rs763844733, COSV59605785; called by muse, mutect2, varscan2
- AC013489.1 | c.513dup p.E172* | Frame Shift Ins (INS) | VAF 68/295 reads (23%) | catalogued as rs943899112; called by mutect2, pindel, varscan2
- ACSM2B | c.60C>A p.S20R | Missense Mutation (SNP) | VAF 79/302 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.051); catalogued as COSV100312240; called by muse, mutect2, varscan2
- AMY1B | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 54/247 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.243); catalogued as COSV100375566; called by muse, mutect2, varscan2
- ANKEF1 | c.505A>G p.T169A | Missense Mutation (SNP) | VAF 51/265 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.061); catalogued as rs899912434; called by muse, mutect2, varscan2
- ANKRD11 | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV56376575; called by muse, mutect2, varscan2
- ANKRD27 | c.1279G>A p.V427I | Missense Mutation (SNP) | VAF 46/325 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs148138451; called by muse, mutect2, varscan2
- ANKRD44 | c.1442C>T p.S481L | Missense Mutation (SNP) | VAF 68/308 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1414061492; called by muse, mutect2, varscan2
- APBB1IP | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772305627, COSV100882261; called by muse, mutect2, varscan2
- ARPC5 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 148/349 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs370723137, COSV54170871; called by muse, mutect2, varscan2
- ASCC3 | c.3729dup p.Q1244Tfs*4 | Frame Shift Ins (INS) | VAF 29/135 reads (21%) | catalogued as rs764916359; called by mutect2, varscan2
- ATG13 | c.187C>T p.H63Y | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs200546929; called by muse, mutect2, varscan2
- ATP2A1 | c.2714T>C p.V905A | Missense Mutation (SNP) | VAF 84/335 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100706837; called by muse, mutect2, varscan2
- ATXN2L | c.2233C>T p.R745W | Missense Mutation (SNP) | VAF 50/236 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs560637561, COSV100294253; called by muse, mutect2, varscan2
- BAP1 | c.1987G>A p.D663N | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56231252, COSV56238617; called by muse, mutect2, varscan2
- BRCA1 | c.2710G>A p.E904K | Missense Mutation (SNP) | VAF 76/336 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.14); catalogued as CD129122, CM119466, COSV58785223, COSV58786501; called by muse, mutect2, varscan2
- BRINP3 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 76/338 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.988); catalogued as rs369089898; called by muse, mutect2, varscan2
- BSN | c.10552G>A p.G3518R | Missense Mutation (SNP) | VAF 162/526 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774202012; called by muse, mutect2, varscan2
- CBLB | c.2674C>T p.L892F | Missense Mutation (SNP) | VAF 53/214 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.82); catalogued as rs770102636; called by muse, mutect2, varscan2
- CBLN3 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 51/222 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99249694; called by muse, mutect2
- CCDC138 | c.852dup p.Q285Tfs*4 | Frame Shift Ins (INS) | VAF 26/110 reads (24%) | catalogued as rs1334766667; called by mutect2, varscan2
- CCDC170 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 72/335 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs776716381, COSV53341214; called by muse, mutect2, varscan2
- CEP104 | c.1868A>G p.Y623C | Missense Mutation (SNP) | VAF 49/210 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1238324803, COSV65518935; called by muse, mutect2, varscan2
- CERKL | c.1448A>G p.N483S (on ENST00000339098 / NM_001030311.2; = p.N457S on NM_201548.5) | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs772749822, COSV59203359, COSV59215511; called by muse, mutect2, varscan2
- CLDN7 | c.378del p.F126Lfs*10 | Frame Shift Del (DEL) | VAF 58/238 reads (24%) | catalogued as COSV100598241; called by mutect2, varscan2
- CSMD1 | c.7827G>A p.W2609* (on ENST00000520002; = p.W2608* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 45/240 reads (19%) | catalogued as COSV59324222; called by muse, mutect2, varscan2
- DAG1 | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 92/402 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs771893080; called by muse, mutect2, varscan2
- DBN1 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 142/604 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759263711, COSV52794002; called by muse, mutect2, varscan2
- DCAF8 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 395/746 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); catalogued as rs377306445; called by muse, mutect2, varscan2
- DCHS2 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 127/450 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.193); catalogued as rs1486745316; called by muse, mutect2, varscan2
- DCP1A | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 86/356 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV99588199; called by muse, mutect2, varscan2
- DDR1 | c.608A>G p.Y203C | Missense Mutation (SNP) | VAF 92/369 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.111); catalogued as rs143357711; called by muse, mutect2, varscan2
- DENND4B | c.2518C>T p.R840C | Missense Mutation (SNP) | VAF 51/226 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs750915651, COSV100768785; called by muse, mutect2, varscan2
- DENND5B | c.2906G>A p.G969E | Missense Mutation (SNP) | VAF 50/251 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV100172257; called by muse, mutect2, varscan2
- DNAH2 | c.9756G>T p.K3252N | Missense Mutation (SNP) | VAF 91/342 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs772860846; called by muse, mutect2, varscan2
- DVL1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 156/635 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs150591074; called by muse, mutect2, varscan2
- EIF4G1 | c.3613C>T p.R1205C (on ENST00000346169 / NM_198241.3; = p.R1010C on NM_004953.5) | Missense Mutation (SNP) | VAF 61/300 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs776741558, CM131885, COSV59990924; called by muse, mutect2, varscan2
- EXOC3L4 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 124/540 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs373034943, COSV66295949; called by muse, mutect2, varscan2
- FAM186B | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 73/276 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV57722408; called by muse, mutect2, varscan2
- FAM47A | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 153/585 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); catalogued as COSV100649677; called by muse, mutect2, varscan2
- FAT1 | c.13337A>G p.D4446G | Missense Mutation (SNP) | VAF 103/405 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1442824243; called by muse, mutect2, varscan2
- FAT1 | c.10309G>A p.A3437T | Missense Mutation (SNP) | VAF 74/323 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as rs373448625; called by muse, mutect2, varscan2
- FNDC3B | c.2825G>C p.G942A | Missense Mutation (SNP) | VAF 70/274 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1303689250; called by muse, mutect2, varscan2
- FUT6 | c.671C>G p.S224C | Missense Mutation (SNP) | VAF 134/538 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.84); catalogued as COSV54606900; called by muse, mutect2, varscan2
- GIMAP8 | c.452dup p.N151Kfs*12 | Frame Shift Ins (INS) | VAF 90/368 reads (24%) | catalogued as rs746795576; called by mutect2, varscan2
- GIPC3 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.989); catalogued as COSV100461078; called by muse, mutect2, varscan2
- GLDN | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 162/518 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.215); catalogued as rs534519385; called by muse, mutect2, varscan2
- GLG1 | c.1416G>C p.E472D | Missense Mutation (SNP) | VAF 73/256 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV52669933; called by muse, mutect2, varscan2
- GLT1D1 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 49/216 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.276); catalogued as rs777054537; called by muse, varscan2
- GMPS | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 57/242 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV55810555; called by muse, mutect2, varscan2
- GOLGA8F | c.374A>G p.Q125R (on ENST00000526619; = p.Q331R on NM_001350920.2) | Missense Mutation (SNP) | VAF 22/303 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.601); catalogued as rs1462904868; called by muse, mutect2, varscan2
- GPR108 | c.1381A>G p.I461V (on ENST00000264080 / NM_001080452.1; = p.I219V on NM_020171.2) | Missense Mutation (SNP) | VAF 70/289 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs1427886466; called by muse, mutect2, varscan2
- GRB7 | c.1115T>G p.L372R | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.942); catalogued as COSV58447278; called by muse, varscan2
- GRK2 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 79/340 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs755384357, COSV57951971; called by muse, mutect2, varscan2
- HELZ2 | c.3245G>A p.S1082N (on ENST00000467148 / NM_001037335.2; = p.S513N on NM_033405.3) | Missense Mutation (SNP) | VAF 120/609 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs761923960; called by muse, mutect2, varscan2
- HOXC4 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 184/718 reads (26%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.992); catalogued as rs1209567382; called by muse, mutect2, varscan2
- HSD11B2 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 76/378 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as rs755994842, COSV99341404; called by muse, mutect2, varscan2
- IGHV4-59 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 53/391 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.374); catalogued as rs782643455; called by muse, mutect2, varscan2
- INTS4 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 38/144 reads (26%) | catalogued as rs763345688, COSV101417131; called by muse, mutect2, varscan2
- IP6K1 | c.281A>G p.Y94C | Missense Mutation (SNP) | VAF 94/365 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as rs1007027892; called by muse, mutect2, varscan2
- ITSN2 | c.4795G>A p.G1599S | Missense Mutation (SNP) | VAF 71/266 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1300802566, COSV100742508; called by muse, mutect2, varscan2
- KCNK2 | c.389T>C p.I130T (on ENST00000444842 / NM_001017425.3; = p.I115T on NM_014217.4) | Missense Mutation (SNP) | VAF 68/264 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV101222069; called by muse, mutect2, varscan2
- KHDC4 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64164847; called by muse, mutect2, varscan2
- KIF24 | c.1982dup p.P662Afs*10 | Frame Shift Ins (INS) | VAF 104/384 reads (27%) | catalogued as rs570788521; called by mutect2, varscan2
- KIF5C | c.669dup p.L224Tfs*9 | Frame Shift Ins (INS) | VAF 50/231 reads (22%) | catalogued as rs753168332; called by mutect2, varscan2
- KIFC1 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 123/583 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs368995550; called by muse, mutect2, varscan2
- LAMB1 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 72/489 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.177); catalogued as rs760878737; called by muse, mutect2, varscan2
- LCE1D | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 104/456 reads (23%) | PolyPhen benign (0); catalogued as rs769606443, COSV58271665; called by muse, varscan2
- LRRC73 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs371800481, COSV99446642; called by muse, mutect2, varscan2
- MAGEA12 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 90/354 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as COSV63295426; called by muse, mutect2, varscan2
- MAN2A1 | c.1394C>G p.S465* | Nonsense Mutation (SNP) | VAF 50/260 reads (19%) | catalogued as COSV99079258; called by muse, mutect2, varscan2
- MAP3K12 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV57233895; called by muse, mutect2, varscan2
- MCM3AP | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 69/257 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs139188881; called by muse, mutect2, varscan2
- MCM7 | c.1165C>T p.Q389* | Nonsense Mutation (SNP) | VAF 64/430 reads (15%) | catalogued as rs774774371, COSV57993728; called by muse, mutect2, varscan2
- MECR | c.861dup p.M288Dfs*16 | Frame Shift Ins (INS) | VAF 79/379 reads (21%) | catalogued as rs752871814; called by mutect2, pindel, varscan2
- MIA2 | c.647C>G p.S216C | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as COSV54503432; called by muse, mutect2, varscan2
- MIER1 | c.1000G>A p.E334K (on ENST00000355356 / NM_001077701.3; = p.E351K on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100590823; called by muse, mutect2, varscan2
- MOS | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 69/356 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.255); catalogued as rs1395941665, COSV61336304; called by muse, mutect2, varscan2
- MRGBP | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 237/568 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1157382691; called by muse, mutect2, varscan2
- MYO5B | c.238C>T p.L80F | Missense Mutation (SNP) | VAF 85/363 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1218772348, COSV53221764; called by muse, mutect2, varscan2
- NUTM2B | c.2553dup p.L852Afs*13 | Frame Shift Ins (INS) | VAF 17/130 reads (13%) | catalogued as rs1193333812; called by mutect2, pindel, varscan2
- NUTM2D | c.2337dup p.L780Afs*13 | Frame Shift Ins (INS) | VAF 27/288 reads (9%) | catalogued as rs1264094263; called by mutect2, pindel, varscan2
- NYAP2 | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 149/583 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.138); catalogued as rs761588621, COSV56005652, COSV56016052, COSV99796255; called by muse, mutect2, varscan2
- OR1N2 | c.413C>A p.S138Y | Missense Mutation (SNP) | VAF 106/372 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV65460137; called by muse, mutect2, varscan2
- OXER1 | c.231dup p.S78Vfs*61 | Frame Shift Ins (INS) | VAF 98/357 reads (27%) | catalogued as rs753912794; called by mutect2, varscan2
- PABPN1 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 60/246 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as COSV53729918; called by muse, mutect2, varscan2
- PCDH17 | c.3107C>T p.S1036L | Missense Mutation (SNP) | VAF 109/452 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.143); catalogued as COSV64974018; called by muse, mutect2, varscan2
- PCIF1 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 57/313 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.272); catalogued as rs377028795; called by muse, mutect2, varscan2
- PCNT | c.1438A>G p.S480G | Missense Mutation (SNP) | VAF 68/271 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs199807929; called by muse, mutect2, varscan2
- PDPR | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 34/444 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs372542476; called by muse, mutect2
- PIAS3 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 81/301 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs782185737; called by muse, mutect2, varscan2
- PLS3 | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 53/207 reads (26%) | catalogued as COSV99171740; called by muse, mutect2, varscan2
- POF1B | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 115/452 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.354); catalogued as rs1046303617; called by muse, mutect2, varscan2
- PRDM1 | c.657G>A p.M219I | Missense Mutation (SNP) | VAF 55/218 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV64845340, COSV64846365; called by muse, mutect2, varscan2
- PRKCA | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 82/279 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV52588777; called by muse, mutect2, varscan2
- PRRT4 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 116/590 reads (20%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV71055157; called by muse, mutect2, varscan2
- PRRT4 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 87/439 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs1262813587; called by muse, mutect2, varscan2
- PTPN14 | c.1707dup p.Y570Lfs*131 | Frame Shift Ins (INS) | VAF 111/598 reads (19%) | catalogued as rs1202548219, COSV100872944; called by mutect2, pindel, varscan2
- PTPRR | c.448C>G p.Q150E | Missense Mutation (SNP) | VAF 79/382 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.93); catalogued as rs780196530; called by muse, mutect2, varscan2
- RARS2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 116/390 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs201899366, COSV57638114, COSV57641021; called by muse, mutect2, varscan2
- RASGRF1 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 69/253 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs967273029, COSV69179491; called by muse, mutect2, varscan2
- RBMXL2 | c.746G>T p.R249L | Missense Mutation (SNP) | VAF 123/481 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV60981423; called by muse, mutect2, varscan2
- REM2 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 124/564 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1490801103, COSV57465782; called by muse, mutect2, varscan2
- RIMS2 | c.3983G>A p.R1328H | Missense Mutation (SNP) | VAF 92/353 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs775941559, COSV51702799; called by muse, mutect2, varscan2
- RLF | c.4715G>A p.R1572H | Missense Mutation (SNP) | VAF 65/267 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV65652562; called by muse, mutect2, varscan2
- RNF32 | c.199dup p.T67Nfs*17 | Frame Shift Ins (INS) | VAF 70/342 reads (20%) | catalogued as rs771776056; called by mutect2, varscan2
- RPAP2 | c.1583T>C p.I528T | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs781126526; called by muse, mutect2, varscan2
- RUFY1 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 42/211 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as rs774539176, COSV60158539, COSV60164200; called by muse, mutect2, varscan2
- RUNX1T1 | c.1501G>A p.A501T (on ENST00000265814 / NM_001198628.1; = p.A474T on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/373 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.94); catalogued as rs1310406617, COSV56137869, COSV56160251; called by muse, mutect2, varscan2
- RYR2 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 68/407 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs754259295, COSV63678919; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SBDS | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 52/228 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217811332; called by muse, mutect2, varscan2
- SBNO1 | c.425C>T p.A142V (on ENST00000420886; = p.A141V on NM_018183.5) | Missense Mutation (SNP) | VAF 76/278 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as COSV57345043; called by muse, mutect2, varscan2
- SCARF2 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 72/229 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs748485923; called by muse, mutect2, varscan2
- SCN4B | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 82/342 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.224); catalogued as rs768926261, COSV61252684; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN9A | c.3397C>T p.P1133S (on ENST00000303354; = p.P1122S on NM_002977.3) | Missense Mutation (SNP) | VAF 81/347 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as rs761748478, COSV100311967; called by muse, mutect2, varscan2
- SLC26A1 | c.1802C>T p.A601V | Missense Mutation (SNP) | VAF 132/548 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs370195125; called by muse, varscan2
- SLC27A2 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 91/411 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99983152; called by muse, mutect2, varscan2
- SLC4A3 | c.3149C>T p.T1050M | Missense Mutation (SNP) | VAF 136/566 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1448736226; called by muse, mutect2, varscan2
- SLC6A15 | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs759900549; called by muse, mutect2, varscan2
- SMARCA4 | c.2681C>T p.T894M | Missense Mutation (SNP) | VAF 101/486 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60797538; called by muse, mutect2, varscan2
- SMARCD2 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 115/379 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762898379; called by muse, mutect2, varscan2
- SP8 | c.575C>T p.S192L (on ENST00000361443 / NM_198956.4; = p.S210L on NM_182700.6) | Missense Mutation (SNP) | VAF 145/414 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.216); catalogued as rs1391027524, COSV100815376; called by muse, mutect2, varscan2
- SRGAP2 | c.2479G>A p.D827N (on ENST00000624873 / NM_001170637.4; = p.D828N on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 152/400 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs782524607; called by muse, mutect2, varscan2
- SUDS3 | c.782A>G p.K261R | Missense Mutation (SNP) | VAF 61/278 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); catalogued as rs750399686; called by muse, mutect2, varscan2
- SYPL2 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 109/463 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.396); catalogued as rs1238108315; called by muse, mutect2, varscan2
- TAB3 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 71/284 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.135); catalogued as rs752852470, COSV55835064; called by muse, mutect2, varscan2
- TDRD1 | c.928G>C p.D310H | Missense Mutation (SNP) | VAF 56/244 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.847); catalogued as rs1564947692; called by muse, mutect2, varscan2
- TECTA | c.3860C>T p.S1287F | Missense Mutation (SNP) | VAF 126/479 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.202); catalogued as COSV99880543; called by muse, mutect2, varscan2
- THAP7 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 146/536 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.487); catalogued as COSV53144783; called by muse, mutect2, varscan2
- THBS2 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 80/304 reads (26%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.003); catalogued as rs202062355; called by muse, mutect2
- THRAP3 | c.1771C>T p.R591C | Missense Mutation (SNP) | VAF 70/252 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as rs1165941817; called by muse, mutect2, varscan2
- TIGD4 | c.708G>C p.K236N | Missense Mutation (SNP) | VAF 95/342 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58549429; called by muse, mutect2, varscan2
- TLE6 | c.1639T>C p.C547R (on ENST00000246112 / NM_001143986.2; = p.C424R on NM_024760.3) | Missense Mutation (SNP) | VAF 65/326 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766930705; called by muse, mutect2, varscan2
- TRAPPC12 | c.1775A>G p.Q592R | Missense Mutation (SNP) | VAF 62/251 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1408707837, COSV60845187; called by muse, mutect2, varscan2
- TRRAP | c.5299G>A p.E1767K (on ENST00000359863 / NM_001244580.1; = p.E1749K on NM_003496.3) | Missense Mutation (SNP) | VAF 54/277 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs1554417925; called by muse, mutect2, varscan2
- TUBA3D | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 116/489 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.298); catalogued as rs753752290; called by muse, mutect2, varscan2
- URB2 | c.1879T>C p.Y627H | Missense Mutation (SNP) | VAF 92/404 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1422359884; called by muse, mutect2, varscan2
- USP35 | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 123/474 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as rs908674003; called by muse, mutect2, varscan2
- UTP20 | c.4328A>G p.D1443G | Missense Mutation (SNP) | VAF 74/277 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as rs756016136, COSV99882520; called by muse, mutect2, varscan2
- VARS2 | c.1183C>G p.P395A | Missense Mutation (SNP) | VAF 84/384 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1378746858; called by muse, mutect2, varscan2
- VPS37B | c.736dup p.R246Pfs*88 | Frame Shift Ins (INS) | VAF 73/325 reads (22%) | catalogued as rs747337112; called by mutect2, varscan2
- XKR4 | c.486C>G p.F162L | Missense Mutation (SNP) | VAF 89/476 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV59310336; called by muse, mutect2, varscan2
- ZBTB37 | c.189G>C p.L63F | Missense Mutation (SNP) | VAF 88/442 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1327976663; called by muse, mutect2, varscan2
- ZFP37 | c.744dup p.H249Tfs*2 | Frame Shift Ins (INS) | VAF 54/387 reads (14%) | catalogued as rs1425115355; called by mutect2, pindel, varscan2
- ZNF106 | c.1444dup p.S482Ffs*17 | Frame Shift Ins (INS) | VAF 68/312 reads (22%) | catalogued as rs1198467282; called by mutect2, varscan2
- ZNF354B | c.812T>C p.I271T | Missense Mutation (SNP) | VAF 78/279 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs777885840; called by muse, mutect2, varscan2
- ZNF718 | c.1286G>A p.G429D | Missense Mutation (SNP) | VAF 43/231 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.35); catalogued as rs538984257; called by muse, mutect2, varscan2
- ZNF727 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 81/450 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1034127441, COSV71646949; called by muse, mutect2, varscan2
- ZNF91 | c.1863G>C p.K621N | Missense Mutation (SNP) | VAF 78/317 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV100322681; called by muse, mutect2, varscan2
- ZYX | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 115/630 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1240732768; called by muse, mutect2, varscan2
- AADAT | c.586A>G p.T196A | Missense Mutation (SNP) | VAF 104/417 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- ADNP2 | c.224G>A p.C75Y | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AIM2 | c.23T>C p.I8T | Missense Mutation (SNP) | VAF 52/257 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- ALCAM | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ALK | c.4044G>T p.M1348I | Missense Mutation (SNP) | VAF 60/250 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ALS2 | c.1513A>G p.R505G | Missense Mutation (SNP) | VAF 80/300 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- ANOS1 | c.1811G>A p.S604N | Missense Mutation (SNP) | VAF 88/349 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- APOBEC3D | c.976G>C p.D326H | Missense Mutation (SNP) | VAF 109/396 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ARID1A | c.971dup p.A325Rfs*75 | Frame Shift Ins (INS) | VAF 131/678 reads (19%) | called by mutect2, pindel, varscan2
- ARID1A | c.5254A>T p.K1752* | Nonsense Mutation (SNP) | VAF 88/357 reads (25%) | called by muse, mutect2, varscan2
- ASH1L | c.7416G>C p.L2472F (on ENST00000368346 / NM_001366177.2; = p.L2467F on NM_018489.3) | Missense Mutation (SNP) | VAF 64/238 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ATRIP | c.2225T>C p.V742A (on ENST00000320211 / NM_130384.3; = p.V715A on NM_032166.4) | Missense Mutation (SNP) | VAF 105/420 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- ATRNL1 | c.3994G>T p.G1332C | Missense Mutation (SNP) | VAF 59/300 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- B3GNT4 | c.113dup p.L38Ffs*47 | Frame Shift Ins (INS) | VAF 132/550 reads (24%) | called by mutect2, pindel, varscan2
- BAHCC1 | c.3665A>G p.E1222G | Missense Mutation (SNP) | VAF 138/566 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BCORL1 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 130/567 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- BMP5 | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 76/352 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CACHD1 | c.2565C>A p.D855E | Missense Mutation (SNP) | VAF 61/319 reads (19%) | SIFT tolerated (1); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CAPN15 | c.2114A>G p.D705G | Missense Mutation (SNP) | VAF 121/502 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- CCDC81 | c.1360G>A p.D454N (on ENST00000445632 / NM_001156474.2; = p.D364N on NM_021827.4) | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- CCDC88A | c.4402dup p.R1468Kfs*12 (on ENST00000436346 / NM_001365480.1; = p.R1467Kfs*12 on NM_001135597.2) | Frame Shift Ins (INS) | VAF 41/198 reads (21%) | called by mutect2, pindel, varscan2
- CD2 | c.696C>G p.F232L | Missense Mutation (SNP) | VAF 78/290 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CDK13 | c.2788T>C p.C930R | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CEP170B | c.4720C>T p.P1574S (on ENST00000453495; = p.P1503S on NM_015005.3) | Missense Mutation (SNP) | VAF 106/467 reads (23%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- CERT1 | c.1281G>C p.K427N (on ENST00000405807 / NM_001130105.1; = p.K299N on NM_005713.3) | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP74 | c.1521dup p.R508Afs*2 | Frame Shift Ins (INS) | VAF 104/491 reads (21%) | called by mutect2, pindel, varscan2
- CHD1 | c.2783dup p.K929Efs*34 | Frame Shift Ins (INS) | VAF 70/320 reads (22%) | called by mutect2, pindel, varscan2
- CIC | c.2689G>A p.A897T | Missense Mutation (SNP) | VAF 137/508 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLIP3 | c.151dup p.L51Pfs*3 | Frame Shift Ins (INS) | VAF 59/266 reads (22%) | called by mutect2, pindel, varscan2
- COL23A1 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 122/559 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- COL4A3 | c.3311G>A p.G1104E | Missense Mutation (SNP) | VAF 73/281 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A2 | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 75/320 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CORO1C | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- CREB3L2 | c.863C>G p.S288* | Nonsense Mutation (SNP) | VAF 91/441 reads (21%) | called by muse, mutect2, varscan2
- CTDP1 | c.1034A>G p.N345S | Missense Mutation (SNP) | VAF 85/305 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DCHS1 | c.4193C>G p.A1398G | Missense Mutation (SNP) | VAF 190/697 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DISP1 | c.1890C>G p.I630M | Missense Mutation (SNP) | VAF 76/357 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DMD | c.7544C>T p.A2515V | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNHD1 | c.8492C>A p.S2831Y | Missense Mutation (SNP) | VAF 79/328 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- DPM2 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 127/494 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- EIF3K | c.480G>T p.E160D | Missense Mutation (SNP) | VAF 99/329 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ELF4 | c.709G>A p.G237S | Missense Mutation (SNP) | VAF 120/566 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPB41L5 | c.2194G>T p.E732* | Nonsense Mutation (SNP) | VAF 73/279 reads (26%) | called by muse, mutect2, varscan2
- FANCI | c.2726T>C p.L909S (on ENST00000310775 / NM_001376911.1; = p.L849S on NM_018193.3) | Missense Mutation (SNP) | VAF 57/216 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- FAT3 | c.3082G>A p.E1028K | Missense Mutation (SNP) | VAF 96/371 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FMN2 | c.2495C>T p.S832F | Missense Mutation (SNP) | VAF 133/591 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- FMR1NB | c.386dup p.F130Lfs*17 | Frame Shift Ins (INS) | VAF 49/224 reads (22%) | called by mutect2, pindel, varscan2
- FN1 | c.2779T>C p.W927R | Missense Mutation (SNP) | VAF 108/445 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FYCO1 | c.3205G>A p.E1069K | Missense Mutation (SNP) | VAF 90/307 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- FZD2 | c.444G>C p.Q148H | Missense Mutation (SNP) | VAF 129/442 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GABPA | c.1109A>G p.N370S | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GABRA2 | c.1065dup p.E356Rfs*51 | Frame Shift Ins (INS) | VAF 26/173 reads (15%) | called by mutect2, pindel, varscan2
- GCN1 | c.7427G>T p.G2476V | Missense Mutation (SNP) | VAF 58/295 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- GLIPR1L2 | c.72G>T p.L24F | Missense Mutation (SNP) | VAF 93/376 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- GMPS | c.610A>G p.K204E | Missense Mutation (SNP) | VAF 73/275 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GOSR1 | c.492G>C p.L164F | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- GSPT2 | c.1088A>G p.Y363C | Missense Mutation (SNP) | VAF 102/432 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GULP1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 60/219 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HERC5 | c.1648_1656dup p.V550_C552dup | In Frame Ins (INS) | VAF 64/278 reads (23%) | called by mutect2, varscan2
- HERPUD1 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 48/278 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- HOXC11 | c.106A>G p.S36G | Missense Mutation (SNP) | VAF 120/497 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- HSPA6 | c.1740dup p.A581Cfs*15 | Frame Shift Ins (INS) | VAF 92/436 reads (21%) | called by mutect2, varscan2
- HYKK | c.152A>G p.Y51C | Missense Mutation (SNP) | VAF 82/302 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- IHO1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 79/297 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- IMMT | c.1665C>T p.S555= | Splice Region (SNP) | VAF 57/182 reads (31%) | called by muse, mutect2, varscan2
- IREB2 | c.377T>C p.V126A | Missense Mutation (SNP) | VAF 60/244 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- IRS4 | c.1106G>T p.G369V | Missense Mutation (SNP) | VAF 183/684 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- ITPRID1 | c.3097T>C p.F1033L | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0); called by mutect2, varscan2
- KCNB2 | c.2542G>A p.E848K | Missense Mutation (SNP) | VAF 74/293 reads (25%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.676); called by muse, mutect2
- KCNH2 | c.3083C>G p.S1028C | Missense Mutation (SNP) | VAF 133/587 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- KCTD8 | c.1418T>C p.L473S | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- KIAA1109 | c.6180G>C p.L2060F | Missense Mutation (SNP) | VAF 51/255 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KLB | c.1117dup p.S373Ffs*15 | Frame Shift Ins (INS) | VAF 87/454 reads (19%) | called by mutect2, pindel, varscan2
- KMT2D | c.3556del p.E1186Kfs*26 | Frame Shift Del (DEL) | VAF 97/456 reads (21%) | called by mutect2, pindel, varscan2
- KNDC1 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 63/289 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRTAP22-1 | c.71G>A p.C24Y | Missense Mutation (SNP) | VAF 93/359 reads (26%) | PolyPhen benign (0.189); called by muse, mutect2, varscan2
- LCN15 | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 66/261 reads (25%) | called by muse, mutect2, varscan2
- LIMD1 | c.829T>C p.S277P | Missense Mutation (SNP) | VAF 130/507 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2
- LMTK3 | c.2175dup p.A726Rfs*814 | Frame Shift Ins (INS) | VAF 46/178 reads (26%) | called by mutect2, varscan2
- MAGEB3 | c.389dup p.P131Afs*16 | Frame Shift Ins (INS) | VAF 76/343 reads (22%) | called by mutect2, varscan2
- MAP3K15 | c.3144C>G p.I1048M | Missense Mutation (SNP) | VAF 59/295 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MDFIC | c.689C>G p.S230* | Nonsense Mutation (SNP) | VAF 69/371 reads (19%) | called by muse, mutect2, varscan2
- MED13 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 83/333 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MED14 | c.2875C>G p.L959V | Missense Mutation (SNP) | VAF 65/246 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- MFSD6 | c.1651T>C p.W551R | Missense Mutation (SNP) | VAF 58/252 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- MRPS14 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MTA3 | c.1522G>C p.E508Q | Missense Mutation (SNP) | VAF 60/239 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MTDH | c.1470G>C p.L490F | Missense Mutation (SNP) | VAF 78/294 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- MYO15B | c.9188A>T p.K3063M | Missense Mutation (SNP) | VAF 117/442 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- MYT1L | c.3202G>A p.E1068K | Missense Mutation (SNP) | VAF 53/254 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- NAA11 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 96/380 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NBPF9 | c.1942G>C p.E648Q | Missense Mutation (SNP) | VAF 22/558 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- NEB | c.19527dup p.D6510* | Frame Shift Ins (INS) | VAF 36/187 reads (19%) | called by mutect2, pindel, varscan2
- NFASC | c.1342A>T p.T448S (on ENST00000339876 / NM_001378329.1; = p.T459S on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/468 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.102); called by muse, mutect2
- OR5P3 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 92/413 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OVCH2 | c.788T>C p.L263S | Missense Mutation (SNP) | VAF 88/366 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- P4HA1 | c.325+1G>A p.X109_splice | Splice Site (SNP) | VAF 35/164 reads (21%) | called by muse, mutect2, varscan2
- PABPC4L | c.983A>C p.E328A | Missense Mutation (SNP) | VAF 88/341 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PBX3 | c.571A>G p.T191A | Missense Mutation (SNP) | VAF 68/292 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- PCDH11X | c.2969G>A p.S990N | Missense Mutation (SNP) | VAF 151/651 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHA11 | c.778C>G p.L260V | Missense Mutation (SNP) | VAF 69/279 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PDE11A | c.1290C>G p.D430E | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- PHACTR2 | c.896G>A p.R299K | Missense Mutation (SNP) | VAF 114/462 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHTF1 | c.1888C>G p.Q630E | Missense Mutation (SNP) | VAF 71/306 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PIGA | c.832T>C p.Y278H | Missense Mutation (SNP) | VAF 7/249 reads (3%) | SIFT tolerated (0.53); PolyPhen benign (0.317); called by muse, mutect2
- PLPP6 | c.263A>T p.E88V | Missense Mutation (SNP) | VAF 146/582 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, varscan2
- PNPLA7 | c.439G>T p.G147C | Missense Mutation (SNP) | VAF 63/261 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POMT1 | c.113G>C p.R38P | Missense Mutation (SNP) | VAF 68/312 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POMT2 | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 130/541 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- POTEE | c.995C>G p.S332C | Missense Mutation (SNP) | VAF 66/468 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- POTEE | c.2041G>T p.E681* | Nonsense Mutation (SNP) | VAF 71/380 reads (19%) | called by muse, mutect2, varscan2
- PPEF1 | c.1566G>C p.W522C | Missense Mutation (SNP) | VAF 100/406 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP1R26 | c.29T>C p.V10A | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- PRDM2 | c.4607C>T p.A1536V | Missense Mutation (SNP) | VAF 90/314 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- PRMT5 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 74/273 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PRR30 | c.88T>C p.S30P | Missense Mutation (SNP) | VAF 91/394 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- PRR5 | c.855G>T p.E285D (on ENST00000336985 / NM_181333.4; = p.E276D on NM_015366.4) | Missense Mutation (SNP) | VAF 118/572 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PRR5L | c.832dup p.E278Gfs*42 | Frame Shift Ins (INS) | VAF 130/543 reads (24%) | called by mutect2, pindel, varscan2
- PTCHD4 | c.1912A>G p.I638V | Missense Mutation (SNP) | VAF 126/452 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- PTPN13 | c.1298G>C p.R433T | Missense Mutation (SNP) | VAF 61/242 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTPRZ1 | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- RBKS | c.760A>G p.I254V | Missense Mutation (SNP) | VAF 80/302 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RCOR1 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- RIN2 | c.2441G>A p.R814K (on ENST00000255006 / NM_001242581.1; = p.R765K on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/364 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- RPE65 | c.1130C>A p.A377D | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- RSL1D1 | c.1286A>C p.E429A | Missense Mutation (SNP) | VAF 125/437 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAC3D1 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 172/676 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SH3BP4 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 106/405 reads (26%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLBP | c.9C>G p.C3W | Missense Mutation (SNP) | VAF 270/626 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- SLC25A33 | c.818A>G p.Q273R | Missense Mutation (SNP) | VAF 58/318 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- SLC27A2 | c.773A>T p.D258V | Missense Mutation (SNP) | VAF 90/410 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLCO1B1 | c.1950dup p.Y651Ifs*17 | Frame Shift Ins (INS) | VAF 27/171 reads (16%) | called by mutect2, pindel, varscan2
- SMOX | c.317A>G p.E106G | Missense Mutation (SNP) | VAF 111/444 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMYD1 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 74/287 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- SOGA1 | c.1343T>C p.V448A | Missense Mutation (SNP) | VAF 118/554 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SOX8 | c.1218dup p.C407Lfs*73 | Frame Shift Ins (INS) | VAF 149/647 reads (23%) | called by mutect2, pindel, varscan2
- SPEN | c.2363dup p.N788Kfs*2 | Frame Shift Ins (INS) | VAF 53/282 reads (19%) | called by mutect2, pindel, varscan2
- SPTBN1 | c.764-1G>C p.X255_splice | Splice Site (SNP) | VAF 43/169 reads (25%) | called by muse, mutect2, varscan2
- SRSF8 | c.625C>A p.H209N | Missense Mutation (SNP) | VAF 104/399 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- STAG1 | c.519dup p.F174Ifs*7 | Frame Shift Ins (INS) | VAF 65/262 reads (25%) | called by mutect2, pindel, varscan2
- STAG2 | c.2453A>G p.D818G | Missense Mutation (SNP) | VAF 99/400 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- STIL | c.177G>C p.E59D | Missense Mutation (SNP) | VAF 60/266 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- SULT4A1 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 106/431 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- SVIL | c.3014A>G p.N1005S (on ENST00000355867 / NM_021738.3; = p.N579S on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/389 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYCP2 | c.4190G>C p.R1397T | Missense Mutation (SNP) | VAF 50/329 reads (15%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAF11L14 | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- TCF7 | c.368C>G p.S123C | Missense Mutation (SNP) | VAF 90/430 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- TERT | c.443T>C p.V148A | Missense Mutation (SNP) | VAF 203/784 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- TET3 | c.5192G>A p.G1731D | Missense Mutation (SNP) | VAF 127/516 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TEX49 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TMTC2 | c.1591T>C p.Y531H | Missense Mutation (SNP) | VAF 56/232 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- TNRC6A | c.2099A>T p.Q700L | Missense Mutation (SNP) | VAF 93/361 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- TPBGL | c.802C>G p.R268G | Missense Mutation (SNP) | VAF 149/542 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- TRIOBP | c.4488G>C p.E1496D | Missense Mutation (SNP) | VAF 103/487 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- TRPM3 | c.3772G>A p.A1258T (on ENST00000357533 / NM_001366142.2; = p.A1113T on NM_020952.6) | Missense Mutation (SNP) | VAF 124/447 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- TTC17 | c.1348T>C p.S450P | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TTLL6 | c.1551G>C p.Q517H (on ENST00000393382 / NM_001130918.3; = p.Q210H on NM_173623.3) | Missense Mutation (SNP) | VAF 74/238 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- TTN | c.41539G>T p.D13847Y (on ENST00000591111; = p.D6423Y on NM_003319.4) | Missense Mutation (SNP) | VAF 66/282 reads (23%) | PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TXNRD2 | c.375G>C p.W125C | Missense Mutation (SNP) | VAF 74/283 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC13A | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 90/358 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- USP5 | c.940G>C p.G314R | Missense Mutation (SNP) | VAF 77/370 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- VCAN | c.4717G>C p.E1573Q | Missense Mutation (SNP) | VAF 87/292 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- VIL1 | c.2290C>G p.L764V | Missense Mutation (SNP) | VAF 80/321 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS13A | c.5335T>A p.F1779I | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- WDR33 | c.1609dup p.T537Nfs*6 | Frame Shift Ins (INS) | VAF 80/302 reads (26%) | called by mutect2, varscan2
- WDR75 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- WNK3 | c.4768A>G p.R1590G | Missense Mutation (SNP) | VAF 105/362 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- WNT7B | c.14T>G p.F5C | Missense Mutation (SNP) | VAF 90/348 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- WRN | c.2021C>T p.S674F | Missense Mutation (SNP) | VAF 60/266 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- YY1 | c.690dup p.D231Rfs*3 | Frame Shift Ins (INS) | VAF 44/112 reads (39%) | called by mutect2, varscan2
- YY1AP1 | c.2204_2229del p.Q735Lfs*43 (on ENST00000295566 / NM_139118.2; = p.Q678Lfs*43 on NM_018253.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 43/292 reads (15%) | called by mutect2, varscan2
- ZFP36L1 | c.162dup p.V55Sfs*20 | Frame Shift Ins (INS) | VAF 79/390 reads (20%) | called by mutect2, pindel, varscan2
- ZFP57 | c.719A>G p.Y240C | Missense Mutation (SNP) | VAF 150/596 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZIK1 | c.146G>T p.R49I | Missense Mutation (SNP) | VAF 88/421 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZMYM2 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 46/246 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF382 | c.1028A>G p.E343G | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- ZNF416 | c.1529T>C p.V510A | Missense Mutation (SNP) | VAF 57/334 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF644 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 43/233 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF69 | c.163G>C p.E55Q (on ENST00000429654 / NM_001364730.1; = p.E41Q on NM_021915.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/263 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ZNF69 | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 65/264 reads (25%) | called by muse, mutect2, varscan2
- ZNF69 | c.1409G>C p.R470T | Missense Mutation (SNP) | VAF 80/315 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ZSCAN2 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 102/368 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZXDC | c.2186dup p.Q730Afs*71 | Frame Shift Ins (INS) | VAF 73/302 reads (24%) | called by mutect2, varscan2
- ADAMTSL5 | c.1104C>T p.G368= | Silent (SNP) | VAF 95/350 reads (27%) | catalogued as COSV57860876; called by muse, mutect2, varscan2
- ADNP2 | c.456G>C p.V152= | Silent (SNP) | VAF 63/277 reads (23%) | called by muse, mutect2, varscan2
- AHCYL1 | c.1329C>G p.L443= | Silent (SNP) | VAF 67/304 reads (22%) | called by muse, mutect2, varscan2
- AKR1B1 | c.510C>T p.I170= | Silent (SNP) | VAF 79/436 reads (18%) | called by muse, mutect2, varscan2
- ARHGAP26 | c.150C>T p.L50= | Silent (SNP) | VAF 46/231 reads (20%) | catalogued as rs1417385741; called by muse, mutect2, varscan2
- ARHGEF38 | c.372G>C p.L124= | Silent (SNP) | VAF 45/166 reads (27%) | called by muse, mutect2, varscan2
- ATXN7 | c.666G>A p.L222= | Silent (SNP) | VAF 100/404 reads (25%) | catalogued as rs1181173041; called by muse, mutect2, varscan2
- BCL3 | c.78G>T p.P26= | Silent (SNP) | VAF 128/463 reads (28%) | called by muse, mutect2, varscan2
- BMPR1A | c.1137T>C p.A379= | Silent (SNP) | VAF 67/259 reads (26%) | called by muse, mutect2, varscan2
- CASKIN1 | c.504C>T p.L168= | Silent (SNP) | VAF 81/311 reads (26%) | catalogued as rs368229690, COSV58871316, COSV58874410; called by muse, mutect2, varscan2
- CEP89 | c.741T>C p.N247= | Silent (SNP) | VAF 54/300 reads (18%) | called by muse, mutect2, varscan2
- CES1 | c.603C>A p.V201= | Silent (SNP) | VAF 127/551 reads (23%) | catalogued as COSV62086619; called by muse, mutect2, varscan2
- CFHR5 | c.1452C>A p.L484= | Silent (SNP) | VAF 80/364 reads (22%) | catalogued as COSV99890116; called by muse, mutect2, varscan2
- CLDN7 | c.381C>T p.I127= | Silent (SNP) | VAF 54/222 reads (24%) | called by mutect2, varscan2
- CLK1 | c.1242C>T p.H414= | Silent (SNP) | VAF 39/199 reads (20%) | catalogued as rs376866439, COSV58435675; called by muse, mutect2, varscan2
- CPM | c.1029T>C p.Y343= | Silent (SNP) | VAF 48/225 reads (21%) | catalogued as rs1297617432; called by muse, mutect2
- CT47B1 | c.405C>G p.L135= | Silent (SNP) | VAF 114/471 reads (24%) | catalogued as rs372046159; called by muse, mutect2, varscan2
- CTAGE9 | c.999A>G p.G333= | Silent (SNP) | VAF 59/291 reads (20%) | called by muse, mutect2, varscan2
- CYP27A1 | c.732C>T p.I244= | Silent (SNP) | VAF 117/442 reads (26%) | catalogued as rs1224145759, COSV99298446; called by muse, varscan2
- DSG2 | c.3048G>C p.V1016= | Silent (SNP) | VAF 105/376 reads (28%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.6735G>A p.K2245= | Silent (SNP) | VAF 77/347 reads (22%) | called by muse, mutect2, varscan2
- EPB41L4B | c.228C>T p.S76= | Silent (SNP) | VAF 88/365 reads (24%) | catalogued as rs1417350729; called by muse, mutect2, varscan2
- EPHB2 | c.48C>T p.L16= | Silent (SNP) | VAF 57/242 reads (24%) | catalogued as rs1222553770; called by muse, mutect2, varscan2
- F2 | c.1185C>A p.L395= | Silent (SNP) | VAF 116/417 reads (28%) | called by muse, mutect2, varscan2
- FAM163B | c.27C>T p.T9= | Silent (SNP) | VAF 118/501 reads (24%) | catalogued as rs1233778522; called by muse, mutect2, varscan2
- FMN2 | c.1287C>A p.P429= | Silent (SNP) | VAF 139/706 reads (20%) | called by muse, mutect2, varscan2
- GATC | c.96C>T p.I32= | Silent (SNP) | VAF 115/452 reads (25%) | catalogued as rs547618488; called by muse, mutect2, varscan2
- GRM1 | c.1461T>C p.T487= | Silent (SNP) | VAF 60/242 reads (25%) | called by muse, mutect2, varscan2
- H4C5 | c.273G>A p.L91= | Silent (SNP) | VAF 48/256 reads (19%) | catalogued as rs143252055; called by muse, mutect2, varscan2
- HOXD9 | c.690C>T p.I230= | Silent (SNP) | VAF 78/319 reads (24%) | catalogued as COSV50891302, COSV50893155; called by muse, mutect2, varscan2
- HYDIN | c.7734C>A p.G2578= | Silent (SNP) | VAF 82/328 reads (25%) | called by muse, mutect2, varscan2
- IFNA5 | c.273C>T p.F91= | Silent (SNP) | VAF 41/232 reads (18%) | called by muse, mutect2, varscan2
- IQGAP3 | c.4872C>T p.L1624= | Silent (SNP) | VAF 78/283 reads (28%) | catalogued as rs943078217; called by muse, mutect2, varscan2
- JRK | c.1521C>T p.F507= | Silent (SNP) | VAF 145/560 reads (26%) | called by muse, mutect2, varscan2
- LRRK1 | c.3781C>A p.R1261= | Silent (SNP) | VAF 117/535 reads (22%) | called by muse, mutect2, varscan2
- MAP7D3 | c.2493T>C p.S831= | Silent (SNP) | VAF 91/361 reads (25%) | called by muse, mutect2, varscan2
- MAPK8IP1 | c.501T>C p.F167= | Silent (SNP) | VAF 90/371 reads (24%) | called by muse, mutect2, varscan2
- MCM10 | c.2487G>A p.P829= (on ENST00000484800 / NM_182751.3; = p.P828= on NM_018518.5) | Silent (SNP) | VAF 49/247 reads (20%) | catalogued as rs372798272, COSV66335597; called by muse, mutect2, varscan2
- MYO18B | c.1206C>T p.S402= | Silent (SNP) | VAF 110/402 reads (27%) | catalogued as rs768901054; called by muse, mutect2, varscan2
- NAV1 | c.4065G>A p.E1355= | Silent (SNP) | VAF 83/464 reads (18%) | catalogued as rs1277615553; called by muse, mutect2, varscan2
- OR5M1 | c.507T>C p.C169= | Silent (SNP) | VAF 88/306 reads (29%) | called by muse, mutect2, varscan2
- OR5P2 | c.555T>C p.C185= | Silent (SNP) | VAF 83/335 reads (25%) | catalogued as rs1564822470; called by muse, mutect2, varscan2
- ORAI3 | c.147C>A p.L49= | Silent (SNP) | VAF 104/414 reads (25%) | called by muse, varscan2
- PCDHB4 | c.2256G>A p.V752= | Silent (SNP) | VAF 111/421 reads (26%) | catalogued as rs1274994724; called by muse, mutect2, varscan2
- PLD3 | c.594C>T p.G198= | Silent (SNP) | VAF 64/299 reads (21%) | catalogued as rs777000690, COSV100735188; called by muse, mutect2, varscan2
- PLXNC1 | c.3591T>C p.S1197= | Silent (SNP) | VAF 72/252 reads (29%) | called by muse, mutect2, varscan2
- POLRMT | c.2034G>A p.T678= | Silent (SNP) | VAF 125/473 reads (26%) | catalogued as rs764634058; called by muse, mutect2, varscan2
- PPME1 | c.78G>A p.Q26= | Silent (SNP) | VAF 113/402 reads (28%) | called by muse, mutect2, varscan2
- PTCHD1 | c.1425G>A p.A475= | Silent (SNP) | VAF 154/644 reads (24%) | catalogued as rs753646890, COSV65059299; called by muse, mutect2, varscan2
- RALGAPA2 | c.5589C>A p.P1863= | Silent (SNP) | VAF 53/216 reads (25%) | called by muse, mutect2, varscan2
- RFT1 | c.1545A>G p.T515= | Silent (SNP) | VAF 70/398 reads (18%) | called by muse, mutect2, varscan2
- RPP38 | c.726T>C p.P242= | Silent (SNP) | VAF 68/272 reads (25%) | catalogued as rs1185868788, COSV65382505; called by muse, mutect2, varscan2
- RYR1 | c.5436G>A p.L1812= | Silent (SNP) | VAF 117/492 reads (24%) | catalogued as rs763007509; called by muse, mutect2, varscan2
- RYR2 | c.4779C>T p.H1593= | Silent (SNP) | VAF 106/541 reads (20%) | catalogued as rs769774527, COSV63698690; called by muse, mutect2, varscan2
- SACS | c.11781G>A p.A3927= | Silent (SNP) | VAF 85/362 reads (23%) | catalogued as rs369998705, COSV66537269; ClinVar: likely benign; called by muse, mutect2, varscan2
- SALL4 | c.411C>T p.G137= | Silent (SNP) | VAF 88/515 reads (17%) | catalogued as rs201560082, COSV53851373; called by muse, mutect2, varscan2
- SEMA3A | c.2232T>C p.S744= | Silent (SNP) | VAF 73/365 reads (20%) | called by muse, mutect2, varscan2
- SLC17A8 | c.1545C>G p.L515= | Silent (SNP) | VAF 106/413 reads (26%) | called by muse, mutect2, varscan2
- SMAD6 | c.999C>T p.S333= | Silent (SNP) | VAF 152/577 reads (26%) | catalogued as rs530424224, COSV56597300; called by muse, mutect2, varscan2
- SMARCAD1 | c.303C>T p.V101= | Silent (SNP) | VAF 43/216 reads (20%) | catalogued as rs757704006, COSV62774491; called by muse, mutect2, varscan2
- SPATA31A3 | c.195A>G p.P65= | Silent (SNP) | VAF 55/286 reads (19%) | called by muse, mutect2, varscan2
- STK11IP | c.1149G>A p.V383= | Silent (SNP) | VAF 79/289 reads (27%) | called by muse, mutect2, varscan2
- STOX2 | c.2682A>G p.P894= | Silent (SNP) | VAF 121/394 reads (31%) | called by muse, mutect2, varscan2
- SUCNR1 | c.930G>A p.L310= | Silent (SNP) | VAF 47/242 reads (19%) | catalogued as COSV62912339, COSV62912603; called by muse, mutect2, varscan2
- SVEP1 | c.3888G>T p.V1296= | Silent (SNP) | VAF 66/309 reads (21%) | catalogued as COSV57029637; called by muse, mutect2, varscan2
- TLX1 | c.153C>T p.V51= | Silent (SNP) | VAF 133/653 reads (20%) | catalogued as rs1157646743; called by muse, mutect2, varscan2
- TMEM238L | c.84C>T p.V28= | Silent (SNP) | VAF 119/398 reads (30%) | catalogued as rs776796060; called by muse, mutect2, varscan2
- TNN | c.1674T>C p.I558= | Silent (SNP) | VAF 75/369 reads (20%) | catalogued as COSV53437545; called by muse, mutect2, varscan2
- TOP2B | c.2562T>C p.N854= (on ENST00000264331 / NM_001330700.2; = p.N849= on NM_001068.3) | Silent (SNP) | VAF 81/377 reads (21%) | called by muse, mutect2, varscan2
- TRRAP | c.156C>G p.V52= | Silent (SNP) | VAF 42/229 reads (18%) | called by muse, mutect2, varscan2
- TSPYL6 | c.984C>T p.I328= | Silent (SNP) | VAF 120/421 reads (29%) | catalogued as COSV57819400; called by muse, mutect2, varscan2
- TTC39C | c.960C>T p.F320= (on ENST00000317571 / NM_001135993.2; = p.F259= on NM_153211.4) | Silent (SNP) | VAF 66/229 reads (29%) | catalogued as COSV58218834; called by muse, mutect2, varscan2
- TUSC3 | c.387T>C p.S129= | Silent (SNP) | VAF 10/346 reads (3%) | catalogued as COSV65880970; called by muse, mutect2
- VPS26B | c.681G>A p.T227= | Silent (SNP) | VAF 64/307 reads (21%) | catalogued as rs377264877; called by muse, mutect2, varscan2
- WNT1 | c.165G>A p.L55= | Silent (SNP) | VAF 92/412 reads (22%) | called by muse, mutect2, varscan2
- XPO7 | c.1383C>G p.L461= | Silent (SNP) | VAF 64/279 reads (23%) | called by muse, mutect2, varscan2
- YBX2 | c.468A>G p.E156= | Silent (SNP) | VAF 63/313 reads (20%) | called by muse, mutect2, varscan2
- ZNF180 | c.1719G>A p.G573= | Silent (SNP) | VAF 104/413 reads (25%) | called by muse, mutect2, varscan2
- ZNF267 | c.1032T>C p.P344= | Silent (SNP) | VAF 71/237 reads (30%) | called by muse, mutect2, varscan2
- ZNF33B | c.1704C>G p.L568= | Silent (SNP) | VAF 67/281 reads (24%) | catalogued as rs1441180282; called by muse, mutect2, varscan2
- ZNF391 | c.804G>A p.Q268= | Silent (SNP) | VAF 91/403 reads (23%) | called by muse, mutect2, varscan2
- ZNF571 | c.1806T>C p.T602= | Silent (SNP) | VAF 56/267 reads (21%) | called by muse, mutect2, varscan2
- ZNF701 | c.762T>C p.I254= (on ENST00000301093; = p.I188= on NM_018260.3) | Silent (SNP) | VAF 71/292 reads (24%) | called by muse, mutect2, varscan2
- ZNF827 | c.1935G>A p.R645= | Silent (SNP) | VAF 41/205 reads (20%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73845730 A>G | 5'Flank (SNP) | VAF 31/172 reads (18%) | called by muse, mutect2, varscan2
- C4orf50 | chr4:5990265 C>A | 5'Flank (SNP) | VAF 76/326 reads (23%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*4082dup | 3'UTR (INS) | VAF 30/170 reads (18%) | called by mutect2, pindel, varscan2
- DENND1A | c.1577+1532A>G | Intron (SNP) | VAF 88/413 reads (21%) | called by muse, mutect2, varscan2
- FOXO3B | chr17:18663054 G>C | 3'Flank (SNP) | VAF 96/334 reads (29%) | called by muse, mutect2, varscan2
- FSD1L | c.1026-3904C>G | Intron (SNP) | VAF 36/176 reads (20%) | catalogued as rs1447548342, COSV65998027; called by muse, mutect2, varscan2
- GAK | c.-91C>G | 5'UTR (SNP) | VAF 248/598 reads (41%) | called by muse, mutect2, varscan2
- ING1 | chr13:110714257 G>A | 5'Flank (SNP) | VAF 68/258 reads (26%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-1076T>C | Intron (SNP) | VAF 72/265 reads (27%) | catalogued as rs1008381246; called by muse, mutect2, varscan2
- KCNQ1 | c.1514+3920T>C | Intron (SNP) | VAF 117/394 reads (30%) | called by muse, mutect2, varscan2
- LINC02363 | n.931G>A | RNA (SNP) | VAF 74/403 reads (18%) | called by muse, mutect2, varscan2
- RPGR | c.2520+892del | Intron (DEL) | VAF 19/95 reads (20%) | catalogued as rs1346308311, CD158282; called by mutect2, pindel, varscan2
- SERPINE3 | chr13:51364253 ins T | 3'Flank (INS) | VAF 78/262 reads (30%) | called by mutect2, pindel, varscan2
- SKA3 | c.*42A>T | 3'UTR (SNP) | VAF 71/275 reads (26%) | called by muse, mutect2, varscan2
- TSPYL4 | c.*1562C>G | 3'UTR (SNP) | VAF 95/357 reads (27%) | called by muse, mutect2, varscan2
- UBALD1 | c.120+23G>A | Intron (SNP) | VAF 181/676 reads (27%) | called by muse, varscan2
- USP2 | c.775-3680C>T | Intron (SNP) | VAF 91/332 reads (27%) | called by muse, mutect2, varscan2
- ZBTB21 | c.-137G>C | 5'UTR (SNP) | VAF 65/373 reads (17%) | called by muse, mutect2, varscan2
